Gene-level copy-number profile of specimen HCM-BROD-0755-C43-85M from HCMI case HCM-BROD-0755-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lentigo maligna melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 62.5 years (22,812 days).
Specimen HCM-BROD-0755-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 27987c44-75e9-4f22-bb62-1a779b008c28.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0755-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/13a01f66-91aa-4bc5-a538-d6319ae1db35

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 656; copy number 2: 11,554; copy number 3: 28,380; copy number 4: 5,833; copy number 5: 5,532; copy number 6: 6,409; copy number 7: 26; copy number 9: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 34 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:43,109,866–61,789,426, 21 genes, copy number 7–9: FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P.
- chr9:61,861,625–61,911,022, 6 genes, copy number 7: AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E.
- chr9:64,439,346–64,498,745, 7 genes, copy number 7: SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.

Autosomal genes at a single copy (total copy number 1): 656. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
